Somatic mutation profile of tumor specimen TCGA-W5-AA2H-01A (aliquot TCGA-W5-AA2H-01A-31D-A417-09) from TCGA case TCGA-W5-AA2H, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 70.6 years (25,775 days).
Specimen TCGA-W5-AA2H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c97f41f-07ed-40a3-82e6-7caaf3c8d34a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA2H-10A (Blood Derived Normal), aliquot TCGA-W5-AA2H-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07bee4e-ba34-4eb0-8d6e-f37ab4b193cd

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MED12 | c.3751G>T p.E1251* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV61341825; called by muse, mutect2
- NDEL1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2
- TMEM87A | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.023); called by muse, mutect2
